Somatic mutation profile of tumor specimen 0DENCU from CCDI case PBBPWH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,332 days).
Specimen 0DENCU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55764175-b1a7-463d-b685-f7830fa5e09b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/920f8a7f-56af-4d34-be5c-188a7d94abd5

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIFM3 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 28/672 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58998908; called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 17/569 reads (3%) | called by muse, mutect2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 26/470 reads (6%) | called by muse, mutect2
- OR13C9 | c.39dup p.L14Sfs*11 | Frame Shift Ins (INS) | VAF 102/568 reads (18%) | called by mutect2, varscan2
- SLC24A5 | c.1153A>C p.I385L | Missense Mutation (SNP) | VAF 22/692 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- ZNF677 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 112/571 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA8 | c.393C>T p.R131= | Silent (SNP) | VAF 20/601 reads (3%) | catalogued as rs1272074020; called by muse, mutect2
- GBP3 | c.1314A>G p.L438= | Silent (SNP) | VAF 178/795 reads (22%) | called by muse, mutect2, varscan2
- GMCL2 | c.1248C>T p.F416= | Silent (SNP) | VAF 44/966 reads (5%) | catalogued as rs776853466; called by muse, mutect2
- KCNJ8 | c.933C>T p.T311= | Silent (SNP) | VAF 27/952 reads (3%) | catalogued as rs1305574342; called by muse, mutect2
- GSK3B | c.813+85G>T | Intron (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2
- GSN | c.817-35G>A | Intron (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
